Gene-level copy-number profile of tumor specimen TCGA-DD-AADP-01A from TCGA case TCGA-DD-AADP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 45.9 years (16,760 days).
Specimen TCGA-DD-AADP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.28ba8fa3-5e88-4d43-b475-7c2fa3ce1e09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bbb3c2f2-694e-49e4-a56e-0f29ba91bb47

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,983; copy number 2: 40,770; copy number 3: 4,819; copy number 4: 38; copy number 5: 38; copy number 6: 45; copy number 9: 44; copy number 12: 40; copy number 14: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADP-01A-11D-A38W-01): tumor purity 0.78, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 204 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:67,317,871–71,845,245, 164 genes, copy number 6–14 (within-gene range 4–14) (broad region; genes not listed).
- chr11:74,171,267–74,311,640, 5 genes, copy number 5 (within-gene range 3–5): PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1.
- chr11:77,659,996–77,821,017, 1 gene, copy number 5 (within-gene range 3–5): RSF1.
- chr11:77,738,680–79,441,030, 34 genes, copy number 5–6 (within-gene range 1–6): RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1.

Autosomal genes at a single copy (total copy number 1): 11,596. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
